CCDI case PBCGNX — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Connective, subcutaneous and other soft tissues.
https://portal.gdc.cancer.gov/cases/b39b7a79-e170-4cc6-bda0-9e9c9274a0ae

Demographics
Sex at birth: female; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Sarcoma, NOS: ICD-O-3 morphology code: 8800/3; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of lower limb and hip; Age at diagnosis: 15.3 years (5,582 days).

Biospecimens (3 samples)
- Sample 0DRIW2: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DRIWA: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DRIWI: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
